Somatic mutation profile of tumor specimen TCGA-85-8072-01A (aliquot TCGA-85-8072-01A-31D-2244-08) from TCGA case TCGA-85-8072, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.4 years (22,069 days).
Specimen TCGA-85-8072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3525cc32-0e50-419f-9d87-6c24f31d038c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8072-10A (Blood Derived Normal), aliquot TCGA-85-8072-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6883b88-f97a-4e6e-aebd-d885f9737f57

The open-access MAF lists 187 somatic variants for this specimen: 142 protein-altering or splice-affecting, 42 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 42, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 2, In Frame Del 2, 3'UTR 1, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 9/294 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119846, COSV57120106, COSV57120715; called by muse, mutect2
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 42/154 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036973; called by muse, mutect2
- AC024598.1 | c.1129+1G>A p.X377_splice | Splice Site (SNP) | VAF 17/78 reads (22%) | catalogued as COSV101237887; called by muse, mutect2, varscan2
- ACTC1 | c.634C>A p.R212S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as COSV51757644, COSV99291859; called by muse, mutect2, varscan2
- ADAMTS20 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs370008149, COSV67130141; called by muse, mutect2
- ADARB2 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.646); catalogued as COSV101186906, COSV67232129; called by muse, mutect2, varscan2
- ADCY1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99812030; called by muse, mutect2, varscan2
- ADCY1 | c.3210G>T p.L1070F | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as COSV52040651, COSV99812032; called by muse, mutect2
- ADCY8 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs750659032, COSV53905147; called by muse, mutect2, varscan2
- ADCY8 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs780136130, COSV53928091; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV58445406; called by muse, mutect2, varscan2
- ADH6 | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV99422335; called by mutect2, varscan2
- APOB | c.7393G>T p.A2465S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV99265592; called by muse, mutect2
- ASAP3 | c.2215C>A p.L739M | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as COSV100369444; called by muse, mutect2, varscan2
- ATP9B | c.2745G>T p.R915S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100303594; called by muse, mutect2
- BACH2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as rs1265099818, COSV99999574; called by muse, mutect2, varscan2
- BACH2 | c.312A>C p.E104D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.054); catalogued as COSV99998840; called by muse, mutect2, varscan2
- BCL2L2 | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV99161543; called by muse, mutect2, varscan2
- CALD1 | c.2018C>G p.S673C (on ENST00000361675 / NM_033138.4; = p.S418C on NM_004342.7) | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100724250; called by muse, mutect2
- CAMTA1 | c.4478C>T p.A1493V | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs147636995; called by muse, mutect2, varscan2
- CAND1 | c.263T>A p.V88E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101598275; called by muse, mutect2
- CAND2 | c.1367G>A p.C456Y (on ENST00000456430 / NM_001162499.2; = p.C363Y on NM_012298.3) | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99929188; called by muse, mutect2, varscan2
- CDC42BPA | c.3697G>C p.A1233P (on ENST00000334218 / NM_001366019.2; = p.A1220P on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505122; called by muse, varscan2
- CDH22 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs376488565; called by muse, mutect2, varscan2
- CDKL5 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV101184325; called by muse, mutect2, varscan2
- CELSR2 | c.3901G>A p.G1301R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99603871; called by muse, mutect2, varscan2
- CHD1L | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100787453; called by muse, mutect2, varscan2
- CHST10 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99958985; called by muse, mutect2, varscan2
- CLCN1 | c.351C>G p.D117E | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV100578080; called by muse, mutect2, varscan2
- CLIC5 | c.788T>A p.L263Q (on ENST00000185206 / NM_001370649.1; = p.L104Q on NM_016929.5) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99484479; called by muse, mutect2, varscan2
- CLIP1 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100211750; called by muse, mutect2
- CNTNAP2 | c.3005A>G p.N1002S | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV100666709; called by muse, mutect2, varscan2
- COL12A1 | c.6913C>T p.P2305S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100486008; called by muse, mutect2, varscan2
- COL22A1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549307992, COSV57323217; called by muse, mutect2, varscan2
- CPXM1 | c.1965G>A p.A655= | Splice Region (SNP) | VAF 9/75 reads (12%) | catalogued as rs770444464, COSV101013736; called by muse, mutect2, varscan2
- DCUN1D2 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100215199; called by muse, mutect2, varscan2
- DLL4 | c.381C>A p.D127E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs780722090, COSV99989824; called by muse, mutect2, varscan2
- DNAH9 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV99305920; called by muse, mutect2, varscan2
- DNAH9 | c.7270C>G p.P2424A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99305921; called by muse, mutect2, varscan2
- DNAH9 | c.10374C>G p.N3458K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV52349308, COSV99305922; called by muse, mutect2, varscan2
- DNHD1 | c.12739G>C p.E4247Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99600130; called by muse, mutect2, varscan2
- DOT1L | c.3512C>G p.P1171R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101288651; called by muse, mutect2, varscan2
- DPPA2 | c.521C>A p.T174K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV101524763; called by muse, mutect2, varscan2
- DST | c.3440G>A p.R1147Q (on ENST00000361203 / NM_001374722.1; = p.R821Q on NM_001723.6) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs756823864, COSV99756129; called by muse, mutect2, varscan2
- DZIP3 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100847795; called by muse, mutect2, varscan2
- EPDR1 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372161085; called by muse, mutect2, varscan2
- ERICH3 | c.2686del p.E896Nfs*4 | Frame Shift Del (DEL) | VAF 91/254 reads (36%) | catalogued as COSV100444949; called by mutect2, pindel, varscan2
- EXOC5 | c.1038G>C p.L346F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100567098; called by muse, mutect2, varscan2
- FAM135B | c.4135G>T p.G1379C | Missense Mutation (SNP) | VAF 87/390 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563664175, COSV52724390, COSV52728224; called by muse, mutect2, varscan2
- FCGR3B | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670544; called by muse, mutect2, varscan2
- FER1L6 | c.5039C>G p.S1680C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205870; called by muse, mutect2, varscan2
- FLG | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 37/695 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs202164130, COSV64244547; called by muse, mutect2
- GABRA4 | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99973876, COSV99974089; called by muse, mutect2, varscan2
- GALNT5 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99375198; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100441156; called by muse, varscan2
- GUCY1A1 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99637793; called by muse, mutect2, varscan2
- GUCY2C | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.448); catalogued as COSV99663655; called by muse, mutect2, varscan2
- H3-3A | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100831299; called by muse, mutect2, varscan2
- H4C4 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1357062906, COSV100534422; called by muse, mutect2, varscan2
- HECTD1 | c.4876A>G p.T1626A | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as rs752035560, COSV101237389; called by muse, mutect2, varscan2
- HOXB6 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV99494518; called by muse, mutect2, varscan2
- IGLV2-14 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs746019377; called by muse, mutect2, varscan2
- INO80D | c.2363A>T p.H788L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.215); catalogued as COSV101305842; called by muse, mutect2, varscan2
- IRGC | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV99746329; called by muse, mutect2, varscan2
- KATNIP | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.213); catalogued as rs754102571, COSV99851137; called by muse, mutect2, varscan2
- KCNH7 | c.307+2T>G p.X103_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100035963; called by muse, mutect2, varscan2
- KCNT1 | c.829G>A p.G277S (on ENST00000488444; = p.G296S on NM_020822.3) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.262); catalogued as COSV53695730; called by muse, mutect2
- KIDINS220 | c.1283T>C p.L428S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99875728; called by muse, mutect2, varscan2
- KMT2C | c.10759C>T p.Q3587* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99030795; called by muse, varscan2
- KY | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV101414993; called by muse, mutect2
- MKI67 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV100896551; called by muse, mutect2, varscan2
- MROH7 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1442381698, COSV100273499, COSV100274188; called by muse, mutect2
- MRPS9 | c.655A>T p.M219L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99306086; called by muse, mutect2, varscan2
- MS4A4A | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV100557812, COSV59703218; called by muse, mutect2, varscan2
- MSH3 | c.3410A>T p.H1137L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99433793; called by muse, mutect2
- MYEF2 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV99981672; called by muse, mutect2, varscan2
- MYT1 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100114702, COSV60510285; called by muse, mutect2, varscan2
- NCAM2 | c.1138T>A p.C380S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99523094; called by muse, mutect2, varscan2
- NCAN | c.3412T>C p.F1138L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.166); catalogued as COSV53051482; called by muse, mutect2, varscan2
- NDST4 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV99996548; called by muse, varscan2
- NEUROD1 | c.76T>G p.C26G | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99716926; called by muse, mutect2, varscan2
- NFATC2 | c.2288T>A p.L763Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV101044104; called by muse, mutect2, varscan2
- NKX2-2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101010524, COSV101010577; called by muse, mutect2, varscan2
- NTRK1 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 78/214 reads (36%) | catalogued as COSV100693340, COSV100693386, COSV62326343; called by muse, mutect2, varscan2
- NUP210 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 132/247 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs777670578, COSV54415178; called by muse, mutect2, varscan2
- OR10K2 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100149494; called by muse, mutect2
- OR2B3 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101013793; called by muse, mutect2
- OR2F2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.123); catalogued as rs762906224, COSV101283817; called by muse, mutect2, varscan2
- OR2M7 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV100522544, COSV58738126; called by muse, mutect2, varscan2
- OR5A1 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV100118362; called by muse, mutect2, varscan2
- PAQR9 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.051); catalogued as COSV100503809; called by muse, mutect2, varscan2
- PARD3B | c.3389C>G p.T1130R (on ENST00000406610 / NM_001302769.2; = p.T1061R on NM_057177.7) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100593488; called by muse, mutect2
- PCDH8 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100131648; called by muse, mutect2, varscan2
- PCDHA12 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100250521; called by muse, mutect2, varscan2
- PCDHGB2 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV99538595; called by muse, mutect2, varscan2
- PIEZO2 | c.7069G>T p.D2357Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99554996; called by muse, mutect2, varscan2
- PKHD1 | c.6191T>C p.L2064S | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100583158; called by muse, mutect2, varscan2
- PLA2G4F | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs748772682, COSV99300652; called by muse, mutect2, varscan2
- PPP2R5E | c.1317A>C p.K439N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100518616; called by muse, mutect2, varscan2
- PREX2 | c.3535C>A p.Q1179K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55793844; called by muse, mutect2
- PREX2 | c.3907G>T p.A1303S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV99907367; called by muse, mutect2, varscan2
- PRSS54 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV99540957; called by muse, mutect2, varscan2
- RNF6 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as COSV100644635; called by muse, mutect2, varscan2
- RUSF1 | c.894C>G p.H298Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs1291166165, COSV100393189; called by muse, mutect2, varscan2
- SH2B1 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV100451065; called by muse, mutect2, varscan2
- SIGLEC1 | c.1957T>C p.C653R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV99165535; called by muse, mutect2, varscan2
- SLC14A1 | c.996+1G>T p.X332_splice | Splice Site (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100425069; called by muse, mutect2, varscan2
- SLC26A8 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 5/128 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.058); catalogued as COSV100839468; called by muse, mutect2
- SLC5A9 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV99361674; called by muse, mutect2, varscan2
- SLCO1B3 | c.1705G>T p.A569S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs763975880, COSV99681468; called by muse, varscan2
- SLFN13 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV99540008; called by mutect2, varscan2
- SLX4 | c.4928C>G p.A1643G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV99568031; called by muse, mutect2, varscan2
- SMARCA5 | c.1619A>G p.D540G | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs761926840, COSV99303856; called by muse, mutect2, varscan2
- SPAM1 | c.857T>A p.I286N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56149551; called by muse, mutect2
- SPOP | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100753385; called by muse, mutect2
- SPTA1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 13/441 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100934980; called by muse, mutect2
- SYNE2 | c.1515G>T p.W505C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100647706; called by muse, varscan2
- TPTE2 | c.1045T>C p.Y349H (on ENST00000400230 / NM_199254.2; = p.Y272H on NM_130785.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.722); catalogued as COSV99690333; called by muse, mutect2
- TRIM23 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99140001; called by muse, mutect2, varscan2
- TRIM6 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99546427; called by muse, mutect2
- TTN | c.50987G>A p.R16996H (on ENST00000591111; = p.R9572H on NM_003319.4) | Missense Mutation (SNP) | VAF 163/250 reads (65%) | PolyPhen probably damaging (0.998); catalogued as rs758627195, COSV100613682, COSV100630189; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.43094G>C p.G14365A (on ENST00000591111; = p.G6941A on NM_003319.4) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | PolyPhen benign (0.031); catalogued as COSV100613688, COSV60108598; called by muse, mutect2
- UGT2B11 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101485254; called by muse, mutect2, varscan2
- UNC79 | c.6808C>A p.L2270I (on ENST00000393151 / NM_001346218.2; = p.L2093I on NM_020818.5) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.74); catalogued as COSV56417377; called by muse, mutect2, varscan2
- USH2A | c.3273G>C p.R1091S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1419913543, COSV100234978; called by muse, mutect2, varscan2
- VPS13C | c.7774A>T p.I2592F (on ENST00000644861 / NM_020821.3; = p.I2549F on NM_017684.5) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as rs1376038660, COSV99828510; called by muse, mutect2, varscan2
- VTN | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs557265411, COSV99879665; called by muse, mutect2, varscan2
- WASF3 | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV100098715; called by muse, mutect2
- ZBED4 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as rs780292820, COSV99351225; called by muse, mutect2, varscan2
- ZNF16 | c.1928T>A p.V643D | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.933); catalogued as COSV99429661; called by muse, mutect2, varscan2
- ZNF300 | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99199879; called by muse, mutect2, varscan2
- ZNF507 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV100321848; called by muse, mutect2
- ZNF527 | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100648733; called by muse, mutect2, varscan2
- ZNF846 | c.1407G>T p.M469I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as COSV101194329; called by muse, mutect2, varscan2
- ZXDC | c.1751T>C p.L584P | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100306463; called by muse, mutect2
- AADACL2 | c.797_799del p.R266del | In Frame Del (DEL) | VAF 18/115 reads (16%) | called by pindel, varscan2*
- ACTG2 | c.1027G>C p.G343R | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAZAP1 | c.547del p.X183_splice | Splice Site (DEL) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- SYNJ2BP | c.178_196del p.Q60Ffs*3 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel
- ZIC5 | c.1166_1168del p.R389del | In Frame Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- APOA1 | c.423G>A p.Q141= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99369270; called by muse, mutect2, varscan2
- ARL4C | c.558C>G p.L186= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100326944; called by muse, mutect2, varscan2
- ARMC4 | c.15G>C p.L5= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100536849; called by muse, mutect2, varscan2
- ASH1L | c.3063G>T p.T1021= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100853423; called by muse, mutect2, varscan2
- ATP2B2 | c.465C>T p.A155= | Silent (SNP) | VAF 12/248 reads (5%) | catalogued as rs1004858963, COSV59508403; called by muse, mutect2
- C8A | c.192G>A p.L64= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100776502; called by muse, mutect2, varscan2
- CDHR2 | c.2100C>T p.Y700= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99991628; called by muse, mutect2, varscan2
- CHRNE | c.1143G>A p.A381= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs942583372, COSV99544962; called by muse, mutect2, varscan2
- COL20A1 | c.1869T>G p.T623= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100490600; called by muse, mutect2, varscan2
- CSMD2 | c.301C>T p.L101= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99590140; called by muse, mutect2
- DHX30 | c.2607C>T p.T869= (on ENST00000445061 / NM_138615.3; = p.T830= on NM_014966.3) | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99275413; called by muse, mutect2, varscan2
- EDNRB | c.597C>T p.C199= (on ENST00000377211 / NM_001201397.1; = p.C109= on NM_000115.5) | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100526667; called by muse, mutect2, varscan2
- GFM1 | c.1998A>T p.A666= | Silent (SNP) | VAF 131/248 reads (53%) | catalogued as rs765400655, COSV99962910; called by muse, mutect2, varscan2
- HERC2 | c.9177G>A p.A3059= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs747671034, COSV99873874; called by muse, mutect2, varscan2
- IDO2 | c.270C>A p.L90= (on ENST00000389060; = p.L103= on NM_194294.2) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100584760; called by muse, varscan2
- IGLV2-14 | c.84C>A p.S28= | Silent (SNP) | VAF 80/325 reads (25%) | catalogued as rs374615592; called by muse, mutect2, varscan2
- LCOR | c.4673G>A p.*1558= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99616894; called by muse, mutect2, varscan2
- MGAT5 | c.708G>T p.R236= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99924503; called by muse, mutect2, varscan2
- MOCS1 | c.357C>A p.I119= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100418623; called by muse, mutect2, varscan2
- MYH11 | c.3340C>A p.R1114= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV100259005; called by muse, mutect2, varscan2
- NEURL1 | c.399C>A p.I133= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100872765; called by muse, mutect2, varscan2
- NLRP3 | c.2421C>G p.A807= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100276071, COSV60232118; called by muse, mutect2, varscan2
- OR2B11 | c.177C>A p.L59= | Silent (SNP) | VAF 61/225 reads (27%) | catalogued as COSV100275091; called by muse, mutect2, varscan2
- OTUD7B | c.213T>C p.S71= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV100967558; called by muse, mutect2, varscan2
- PAQR5 | c.297C>T p.S99= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs1390581566, COSV100575491; called by muse, mutect2, varscan2
- POTED | c.409C>A p.R137= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100203136, COSV55048061; called by muse, mutect2, varscan2
- PRAMEF12 | c.1236T>A p.P412= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as COSV100743286; called by muse, mutect2, varscan2
- RALGDS | c.504C>T p.D168= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs537625899, COSV64428925; called by muse, mutect2, varscan2
- RASA3 | c.2301G>T p.T767= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs141575775, COSV100480563; called by muse, mutect2, varscan2
- RRP12 | c.1839G>A p.K613= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100213192; called by muse, mutect2
- SAMD9L | c.4509A>G p.T1503= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs759047710, COSV100560701, COSV59083439; called by muse, mutect2, varscan2
- SLC17A1 | c.246C>T p.I82= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1020318645, COSV99765783; called by muse, mutect2
- SLC35F1 | c.1093C>A p.R365= | Silent (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- SLC6A2 | c.1116C>T p.H372= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV99573874; called by muse, mutect2, varscan2
- SLX4 | c.4929C>A p.A1643= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1213865580, COSV99568029; called by muse, mutect2, varscan2
- SRRM4 | c.666C>A p.S222= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99938547; called by muse, mutect2, varscan2
- SYNGR3 | c.525C>T p.T175= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99937267; called by muse, mutect2, varscan2
- TP53 | c.837G>T p.G279= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as CD963012, COSV53098982, COSV53696473; called by muse, mutect2, varscan2
- TTN | c.16851T>C p.S5617= (on ENST00000591111; = p.S4690= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100613692, COSV59970123; called by muse, mutect2, varscan2
- VAC14 | c.186G>T p.L62= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV99934619; called by muse, mutect2, varscan2
- ZNF410 | c.393G>A p.L131= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100206446; called by muse, mutect2
- ZNF555 | c.1548T>A p.A516= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100514660; called by muse, mutect2, varscan2
- MFSD4B | c.*619A>G | 3'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as rs767852237, COSV100920588; called by muse, mutect2, varscan2
- MIR147A | n.34A>T | RNA (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895776 del CCAAGATCTTC | 5'Flank (DEL) | VAF 52/136 reads (38%) | called by mutect2, varscan2
